Gene-level copy-number profile of tumor specimen TCGA-IB-A5SS-01A from TCGA case TCGA-IB-A5SS, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 64.2 years (23,431 days).
Specimen TCGA-IB-A5SS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.9c6974e1-ce81-4a5a-b6db-825ace437e07.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IB-A5SS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0a5c37a4-6d16-427a-b0d7-f6565bb4f426

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,108; copy number 2: 41,663; copy number 3: 2,610; copy number 5: 210; copy number 6: 164; copy number 7: 12; copy number 9: 35; copy number 14: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IB-A5SS-01A-11D-A32M-01): tumor purity 0.47, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 439 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:64,654,060–73,208,317, 163 genes, copy number 6–14 (broad region; genes not listed).
- chr12:74,537,835–74,728,851, 5 genes, copy number 6: ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3.
- chr12:93,677,375–95,302,799, 36 genes, copy number 5 (within-gene range 1–5): CRADD, AC012085.2, RN7SL630P, AC012464.2, AC012464.1, AC012464.3, RN7SKP263, AC123567.1, PLXNC1, AC123567.2, AC073655.3, AC073655.1, AC073655.2, CEP83, RN7SL330P, RBMS2P1, CEP83-DT, AC023161.1, RN7SL483P, NSA2P2, SUCLG2P2, MIR5700, TMCC3, MIR7844, LSM3P2, KRT19P2, MIR492, NDUFA12, NR2C1, FGD6, AC126615.2, AC126615.1, VEZT, Y_RNA, CBX3P5, RNU6-808P.
- chr19:8,008,729–9,700,776, 76 genes, copy number 5 (broad region; genes not listed).
- chr19:27,638,483–30,060,797, 61 genes, copy number 6–9 (broad region; genes not listed).
- chr19:38,878,555–40,629,818, 98 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,687. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
